CCDI case PBBKMV — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/77a3251f-d310-4422-a9d9-2b627b173728

Demographics
Sex at birth: female; Race: asian; Vital status: Alive.

Diagnoses (1)
1. Diagnosis record without a diagnosis name: Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.8 years (2,483 days).

Biospecimens (3 samples)
- Sample 0DAXP2: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DAXP5: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DAXP7: Tissue type: Tumor; Specimen type: Solid Tissue.
